Somatic mutation profile of tumor specimen TCGA-CM-6172-01A (aliquot TCGA-CM-6172-01A-11D-1650-10) from TCGA case TCGA-CM-6172, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 70.9 years (25,902 days).
Specimen TCGA-CM-6172-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3f03350-3653-44e4-ac61-a6b6ebf37d26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6172-10A (Blood Derived Normal), aliquot TCGA-CM-6172-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f637ef57-5f6b-4e18-87ca-3f253e70c577

The open-access MAF lists 108 somatic variants for this specimen: 70 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 35, Nonsense Mutation 7, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 126/294 reads (43%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 77/218 reads (35%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 20/128 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 64/108 reads (59%) | catalogued as rs1567555994, CM156961, COSV52702138, COSV53867973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3052C>T p.R1018* (on ENST00000404938 / NM_001163941.2; = p.R573* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 17/133 reads (13%) | catalogued as rs200343372; called by muse, mutect2, varscan2
- ACSBG1 | c.128C>A p.T43N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV51905866, COSV99357244; called by muse, mutect2, varscan2
- ANKAR | c.1993T>A p.W665R | Missense Mutation (SNP) | VAF 46/690 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55612655; called by muse, mutect2
- AVPR1B | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782438962, COSV65638078; called by muse, mutect2, varscan2
- BHLHA15 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.018); catalogued as COSV51995477; called by muse, mutect2, varscan2
- CD200 | c.526T>C p.F176L (on ENST00000473539 / NM_001004196.3; = p.F151L on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV59863214; called by muse, mutect2
- CD38 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1449179627, COSV56890203; called by muse, mutect2, varscan2
- CHD2 | c.2356C>T p.L786F | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV67709107, COSV67714312; called by muse, mutect2, varscan2
- COL15A1 | c.4049C>T p.T1350M | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.287); catalogued as rs374842979; called by muse, mutect2, varscan2
- CPNE2 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV51962345; called by muse, mutect2, varscan2
- CSMD1 | c.9899T>G p.V3300G (on ENST00000520002; = p.V3299G on NM_033225.6) | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100148075; called by muse, mutect2, varscan2
- DCAF4L2 | c.72T>A p.N24K | Missense Mutation (SNP) | VAF 40/559 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV100150907; called by muse, mutect2
- ECEL1 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374411123; called by muse, mutect2, varscan2
- FAM234A | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs755759461; called by mutect2, varscan2
- FAM47C | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 88/134 reads (66%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as rs1556332457, COSV63725336; called by muse, mutect2, varscan2
- FLG | c.4396C>A p.Q1466K | Missense Mutation (SNP) | VAF 199/520 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as COSV100911594; called by muse, mutect2, varscan2
- GATM | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101188254; called by muse, mutect2
- GGCT | c.338C>A p.A113E | Missense Mutation (SNP) | VAF 196/583 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV50040844; called by muse, mutect2, varscan2
- HS3ST2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV54464217; called by mutect2, varscan2
- HTR1E | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs778639081, COSV100541346, COSV59507202; called by muse, mutect2, varscan2
- IGHV3-11 | c.218G>C p.S73T | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs1555434240; called by muse, mutect2
- KCNJ2 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 347/927 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs371331394, COSV54661663; called by muse, mutect2, varscan2
- KIAA1549L | c.4493G>A p.R1498H (on ENST00000321505; = p.R1795H on NM_012194.3) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs560632849, COSV58582008; called by muse, mutect2, varscan2
- KIF1A | c.4844A>C p.Y1615S (on ENST00000320389 / NM_001379639.1; = p.Y1607S on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100240986; called by muse, mutect2, varscan2
- KSR1 | c.1850G>A p.R617H (on ENST00000644974 / NM_001367810.1; = p.R502H on NM_014238.2) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52028209; called by muse, mutect2, varscan2
- MAP2K4 | c.1091A>C p.H364P | Missense Mutation (SNP) | VAF 115/239 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62257243; called by muse, mutect2, varscan2
- MITF | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs752026814, COSV58883050; called by muse, mutect2, varscan2
- MLF2 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV99180083; called by muse, mutect2, varscan2
- MUC16 | c.42667T>G p.Y14223D | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV101109906; called by muse, mutect2
- MYCBPAP | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs201901914, COSV60406649; called by muse, mutect2, varscan2
- NR4A2 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1452459489, COSV59895013; called by muse, mutect2
- NUP210L | c.3229C>T p.R1077W | Missense Mutation (SNP) | VAF 73/313 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs760261503, COSV99668096; called by muse, mutect2, varscan2
- NUTM2G | c.1406A>C p.E469A | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV63617252; called by muse, mutect2
- OR1E2 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV50265629; called by muse, mutect2
- PAPPA | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs774728290, COSV60283021; called by muse, mutect2, varscan2
- PCDH9 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100120831; called by muse, mutect2, varscan2
- PCDHA11 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.287); catalogued as rs782023174, COSV56500171; called by muse, mutect2, varscan2
- PCDHGA7 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.393); catalogued as rs1286843210, COSV53945321; called by muse, mutect2, varscan2
- PTPRS | c.5255C>T p.A1752V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs758652323, COSV53619256; called by muse, mutect2, varscan2
- RASL11B | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 57/134 reads (43%) | catalogued as rs777475073, COSV50535060; called by muse, mutect2, varscan2
- RBCK1 | c.769C>G p.Q257E (on ENST00000356286 / NM_031229.4; = p.Q215E on NM_006462.6) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100675834; called by muse, mutect2, varscan2
- REV1 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 170/471 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV51484985; called by muse, mutect2, varscan2
- RXFP3 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as rs1468466671, COSV100347145; called by muse, mutect2, varscan2
- RYR2 | c.7655T>A p.V2552E | Missense Mutation (SNP) | VAF 157/427 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100770289; called by muse, mutect2, varscan2
- SDK2 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1192577031, COSV66185744; called by muse, mutect2, varscan2
- SFTPA2 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759988686, COSV64882471; called by muse, mutect2, varscan2
- SGCG | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs375766013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPAG1 | c.1865C>T p.T622I | Missense Mutation (SNP) | VAF 181/528 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV52558529; called by muse, mutect2, varscan2
- SPAG9 | c.3868T>A p.S1290T (on ENST00000262013 / NM_001130528.3; = p.S1276T on NM_003971.6) | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV100005204; called by muse, mutect2, varscan2
- SPTA1 | c.6060G>T p.L2020F | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63752822; called by muse, mutect2, varscan2
- TAF1L | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 119/398 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs1338703372, COSV54261651; called by muse, mutect2, varscan2
- TEX47 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 75/246 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV51878925, COSV51879134; called by muse, mutect2, varscan2
- TRIM3 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV61983857; called by muse, mutect2, varscan2
- TTBK1 | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV52488297; called by muse, mutect2, varscan2
- TUBB8 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV59115676; called by muse, mutect2, varscan2
- UBXN6 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs267605469, COSV56672118; called by muse, mutect2, varscan2
- VCAM1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 85/254 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0.013); catalogued as rs200910233; called by muse, mutect2, varscan2
- ZBED9 | c.2300C>A p.A767D | Missense Mutation (SNP) | VAF 22/570 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV101509244; called by muse, mutect2
- ZMYM4 | c.1783T>G p.S595A | Missense Mutation (SNP) | VAF 108/187 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV58910337; called by muse, mutect2, varscan2
- ZNF43 | c.408A>T p.Q136H | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV100731822; called by muse, mutect2, varscan2
- ZNF442 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 101/253 reads (40%) | catalogued as COSV54421480; called by muse, mutect2, varscan2
- ZNF471 | c.870T>G p.Y290* | Nonsense Mutation (SNP) | VAF 26/84 reads (31%) | catalogued as COSV57291212; called by muse, mutect2, varscan2
- ZNF692 | c.919T>A p.W307R | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as COSV60659218; called by muse, mutect2, varscan2
- CEP85L | c.1515G>T p.Q505H | Missense Mutation (SNP) | VAF 29/1084 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- JUN | c.769dup p.R257Kfs*53 | Frame Shift Ins (INS) | VAF 29/128 reads (23%) | called by mutect2, pindel, varscan2
- SETX | c.7433_7437del p.T2478Sfs*35 | Frame Shift Del (DEL) | VAF 79/247 reads (32%) | called by mutect2, pindel, varscan2
- AC004997.1 | c.759C>T p.P253= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV53164188; called by muse, mutect2, varscan2
- ASB12 | c.732C>T p.I244= | Silent (SNP) | VAF 58/104 reads (56%) | catalogued as rs1466875448, COSV62856897; called by muse, mutect2, varscan2
- BEND3 | c.1647C>T p.P549= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs781991805, COSV100944665, COSV64681035; called by muse, mutect2, varscan2
- BOC | c.1623C>T p.P541= | Silent (SNP) | VAF 73/150 reads (49%) | catalogued as rs764762676, COSV56350648; called by muse, mutect2, varscan2
- CDH8 | c.2106A>T p.P702= | Silent (SNP) | VAF 18/220 reads (8%) | catalogued as COSV54889241; called by muse, mutect2
- CPNE2 | c.237C>T p.F79= | Silent (SNP) | VAF 67/136 reads (49%) | catalogued as rs193160367; called by muse, mutect2, varscan2
- CYP2E1 | c.861C>T p.D287= | Silent (SNP) | VAF 64/156 reads (41%) | catalogued as rs527959204, COSV53313067, COSV53313297; called by muse, mutect2, varscan2
- DNAH17 | c.10731G>A p.L3577= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as COSV67754119; called by muse, mutect2, varscan2
- EMILIN1 | c.2676C>A p.V892= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as COSV53154774; called by muse, mutect2, varscan2
- FNBP1 | c.229C>T p.L77= | Silent (SNP) | VAF 92/282 reads (33%) | catalogued as COSV63087308; called by muse, mutect2, varscan2
- GPR88 | c.306C>T p.P102= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs77713845, COSV59291479; called by muse, mutect2, varscan2
- IGKV1D-17 | c.30G>T p.L10= | Silent (SNP) | VAF 69/165 reads (42%) | called by muse, mutect2, varscan2
- KCNK10 | c.861C>T p.N287= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as rs372974329; called by muse, mutect2, varscan2
- LDB2 | c.387C>T p.H129= | Silent (SNP) | VAF 62/159 reads (39%) | catalogued as rs764834270, COSV58769085; called by muse, mutect2, varscan2
- MBNL2 | c.1020C>T p.N340= (on ENST00000376673 / NM_001382666.1; = p.N328= on NM_207304.3 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 107/192 reads (56%) | catalogued as rs750533362, COSV59120730; called by muse, mutect2, varscan2
- MIEF1 | c.900G>A p.V300= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as rs150768628; called by muse, mutect2, varscan2
- NEK6 | c.555C>T p.V185= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs1290681997, COSV57217452; called by muse, mutect2, varscan2
- NIPAL1 | c.519C>G p.G173= | Silent (SNP) | VAF 86/230 reads (37%) | catalogued as COSV55006498; called by muse, mutect2, varscan2
- NPHS1 | c.2436C>T p.G812= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs768441489, COSV62287748; called by muse, mutect2, varscan2
- PDILT | c.1185G>A p.K395= | Silent (SNP) | VAF 85/269 reads (32%) | catalogued as COSV56701849; called by muse, mutect2, varscan2
- PDILT | c.627C>A p.G209= | Silent (SNP) | VAF 50/177 reads (28%) | catalogued as COSV56701856; called by muse, mutect2, varscan2
- POU6F2 | c.867G>A p.T289= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as rs774648361, COSV68873320; called by muse, mutect2, varscan2
- RAMP2 | c.252C>T p.C84= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as rs753752218, COSV53822810; called by muse, mutect2, varscan2
- RIPOR3 | c.966C>T p.F322= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs780003881, COSV50388777, COSV50394018; called by muse, mutect2, varscan2
- SCARA3 | c.1473C>T p.P491= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as COSV57270152; called by muse, mutect2, varscan2
- SLC6A2 | c.774A>G p.T258= | Silent (SNP) | VAF 42/180 reads (23%) | catalogued as rs1331548150, COSV54916370; called by muse, mutect2
- SPTBN2 | c.1705C>T p.L569= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV59451949; called by muse, mutect2, varscan2
- TAAR8 | c.780G>T p.G260= | Silent (SNP) | VAF 13/292 reads (4%) | catalogued as COSV99257204; called by muse, mutect2
- TENM2 | c.3358C>T p.L1120= (on ENST00000518659 / NM_001122679.2; = p.L888= on NM_001080428.3) | Silent (SNP) | VAF 118/311 reads (38%) | catalogued as COSV101318502, COSV69129867; called by muse, mutect2, varscan2
- TMTC4 | c.210C>T p.F70= (on ENST00000376234 / NM_001350577.2; = p.F89= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as COSV60892241; called by muse, mutect2, varscan2
- TOP2B | c.3111A>G p.Q1037= (on ENST00000264331 / NM_001330700.2; = p.Q1032= on NM_001068.3) | Silent (SNP) | VAF 32/419 reads (8%) | catalogued as COSV99979714; called by muse, mutect2
- TOP3A | c.2880G>A p.S960= | Silent (SNP) | VAF 94/148 reads (64%) | catalogued as rs541672157, COSV58177313; called by muse, mutect2, varscan2
- TTN | c.3318C>T p.G1106= (on ENST00000591111; = p.G1060= on NM_003319.4) | Silent (SNP) | VAF 77/203 reads (38%) | catalogued as rs141768043; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- ZC3H4 | c.1680G>A p.P560= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs757017978, COSV53412876; called by muse, mutect2, varscan2
- ZNF35 | c.648G>A p.Q216= | Silent (SNP) | VAF 84/217 reads (39%) | catalogued as COSV56076457; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700999 T>A | 3'Flank (SNP) | VAF 78/224 reads (35%) | called by muse, mutect2, varscan2
- EGFL7 | c.572-295G>T | Intron (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100451975; called by muse, mutect2, varscan2
- EZH1 | c.-1G>T | 5'UTR (SNP) | VAF 95/260 reads (37%) | catalogued as COSV101331364; called by muse, mutect2, varscan2
